HCMI case HCM-WCMC-0675-C67 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Bladder. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5e44aad4-b3e9-4007-9983-e41188b749c9

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age: 90 years or older (exact value withheld by GDC); Vital status: Dead; Days to death: 5,021 days (13.7 years); Cause of death: Cancer Related.

Diagnoses (2)
1. Papillary transitional cell carcinoma (the primary disease): ICD-O-3 morphology code: 8130/3; ICD-10 code: C67.9; Tissue or organ of origin: Bladder, NOS; Classification of tumor: primary; Age at diagnosis: 90 years or older (exact value withheld by GDC); AJCC staging edition: 8th; AJCC clinical stage: Stage X; AJCC pathologic T: TX; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage X; Tumor grade: GX; Metastasis at diagnosis: No Metastasis; Prior malignancy: yes; Prior treatment: Yes.
   Pathology details: Lymph nodes positive: 0; Lymph nodes tested: 0.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Treatment intent type: Neoadjuvant; Days to treatment start: 693 days (1.9 years).
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 693 days (1.9 years).
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Pembrolizumab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 4,400 days (12.0 years); Days to treatment end: 5,021 days (13.7 years).
   Recorded as not given: adjuvant Chemotherapy, for residual disease; adjuvant Hormone Therapy, for residual disease; neoadjuvant Radiation Therapy, NOS; adjuvant Targeted Molecular Therapy, for residual disease.
2. Carcinoma, metastatic, NOS: ICD-O-3 morphology code: 8010/6; ICD-10 code: C79.11; Tissue or organ of origin: Bladder, NOS; Site of resection or biopsy: Ureter; Classification of tumor: metastasis; Age at diagnosis: 90 years or older (exact value withheld by GDC); Days to diagnosis: 4,101 days (11.2 years).

Follow-up (2 entries)
- Days to follow up: 5,021 days (13.7 years); Disease response: Progressive Disease; Progression or recurrence: Yes.
- Follow-up contact recording only the day: day 4,421.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Urinary Tract Infection; Risk factors: Urinary Tract Infection.
- Timepoint category: Initial Diagnosis; Weight: 93.4 kg; Height: 185.4 cm; BMI: 27.

Exposures
- Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Alcohol drinks per day: 0; Alcohol days per week: 0.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-WCMC-0675-C67-02A: Sample type: Slides; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide HCM-WCMC-0675-C67-02A-S2-HE: Section location: Bottom; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 8; Percent necrosis: 0; Percent stromal cells: 17; Percent lymphocyte infiltration: 6; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 4.
  Slide HCM-WCMC-0675-C67-02A-S1-HE: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 8; Percent necrosis: 0; Percent stromal cells: 17; Percent lymphocyte infiltration: 6; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 4.
- Sample HCM-WCMC-0675-C67-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Buffy Coat; Preservation method: Frozen.
- Sample HCM-WCMC-0675-C67-85R: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: 3D Organoid; Preservation method: Cryopreserved; Passage count: 15.
